Somatic mutation profile of tumor specimen TCGA-VD-A8KH-01A (aliquot TCGA-VD-A8KH-01A-11D-A39W-08) from TCGA case TCGA-VD-A8KH, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Overlapping lesion of eye and adnexa; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 69.5 years (25,388 days).
Specimen TCGA-VD-A8KH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 463dfa6e-6e8c-41e6-893d-4dc3e0944284.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-A8KH-10A (Blood Derived Normal), aliquot TCGA-VD-A8KH-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/455b79c8-d09f-492a-bc46-962f0800fc01

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 7, Silent 6, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 29/56 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 24/58 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519961, COSV59205431, COSV59206122, COSV59206364; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANOS1 | c.171G>T p.Q57H | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1411018904; called by muse, mutect2, varscan2
- NCOA2 | c.3149G>A p.S1050N | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1426956925; called by muse, mutect2, varscan2
- MAPK8IP2 | c.104A>C p.E35A | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RBM12 | c.1972C>A p.P658T | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SKA3 | c.131T>A p.L44* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- SLC12A9 | c.1750_1751insT p.A584Vfs*51 | Frame Shift Ins (INS) | VAF 16/63 reads (25%) | called by mutect2, pindel, varscan2
- SOST | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPATCH8 | c.2049A>G p.K683= | Silent (SNP) | VAF 76/177 reads (43%) | called by muse, mutect2, varscan2
- MMP20 | c.345C>G p.P115= | Silent (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- NXPH3 | c.150G>A p.R50= | Silent (SNP) | VAF 49/82 reads (60%) | called by muse, mutect2, varscan2
- PPP1R3B | c.573G>A p.T191= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as rs758018996; called by muse, mutect2, varscan2
- RND2 | c.468G>T p.V156= | Silent (SNP) | VAF 33/80 reads (41%) | called by muse, mutect2, varscan2
- URAD | c.18C>T p.V6= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as rs1249035096; called by muse, mutect2, varscan2
